Gene-level copy-number profile of tumor specimen MP2PRT-PAPDFA-TMP1-A from MP2PRT case MP2PRT-PAPDFA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,392 days).
Specimen MP2PRT-PAPDFA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f7e5436-1720-42fd-bd95-773317ee9a29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPDFA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/82c32ec7-93aa-4c9a-9077-cb711b32eefa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 2,191; copy number 2: 56,657; copy number 3: 22.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–1): IGKV2-14, IGKV3-15.
- chr2:89,134,975–89,192,752, 5 genes (within-gene range 0–1): IGKV2-19, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,244,781–89,254,015, 3 genes (within-gene range 0–1): IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,947,512–89,990,221, 5 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,121,786–90,221,384, 8 genes: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,291,616–38,311,808, 4 genes (within-gene range 0–1): TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
